Gene-level copy-number profile of tumor specimen TCGA-AG-A00Y-01A from TCGA case TCGA-AG-A00Y, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.0 years (24,837 days).
Specimen TCGA-AG-A00Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.0c66bf9f-6285-43f7-8893-007dd42d11df.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A00Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 398 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c4067269-c602-43d3-9922-1a4c0b2c345f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 12,613; copy number 2: 39,884; copy number 3: 6,287; copy number 5: 1,405; copy number 8: 2; copy number 9: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A00Y-01A-02D-A003-01): tumor purity 0.7, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene (within-gene range 0–2): AC010983.1.
- chr5:97,737,894–97,738,913, 1 gene: AC112203.1.
- chr5:114,576,041–114,579,970, 1 gene: LINC01957.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr11:54,591,480–55,326,673, 19 genes: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P.
- chr11:112,977,353–112,977,420, 1 gene: RNU7-187P.
- chr18:29,048,620–29,048,719, 1 gene: RNU6-408P.
- chr19:27,638,483–27,646,483, 2 genes: ERVK-28, AC112702.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,410 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:40,519,565–40,897,833, 2 genes, copy number 8 (within-gene range 1–8): AC010857.1, ZMAT4.
- chr8:41,261,962–41,309,473, 1 gene, copy number 9 (within-gene range 1–9): SFRP1.
- chr8:41,275,115–41,650,817, 13 genes, copy number 5–9: AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3.
- chr8:41,660,441–41,665,566, 3 genes, copy number 5: MIR486-1, MIR486-2, AC113133.1.
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,228. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
